Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00Z, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00Z-01A (Primary Tumor).

ICD-0-3
Adenocarcinoma, NOS 8140/3
Site: Sigmoid colon C18.7 pw 3/29/11

Sample ID #:

Diagnosis:

Resectate of the colon, or sigmoid colon, with tumor-free oral and aboral resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and without regional lymph node metastases (G2, pT3 L1 V0 R0 pN0 0/37).

The unusual appearance of the pericolic lymph nodes based on microscopic examination leads to the question of whether there are clinical indications for a lymphatic leukemia. If CLL has not been diagnosed, then we request to be informed accordingly so that the tissue can potentially be sent on for consultation purposes and further investigation at the Lymph Node Registry in

Source: NCI Genomic Data Commons file b8050557-a85c-4aa3-b069-aae7b16b79ad (TCGA-AA-A00Z.CDC060C5-854A-44FC-946B-66AB98D782A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).